Somatic mutation profile of tumor specimen TCGA-SX-A7SM-01A (aliquot TCGA-SX-A7SM-01A-11D-A34Z-10) from TCGA case TCGA-SX-A7SM, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 60.4 years (22,044 days).
Specimen TCGA-SX-A7SM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09d22334-88f4-4a4d-93ea-4009923bfa88.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SX-A7SM-10A (Blood Derived Normal), aliquot TCGA-SX-A7SM-10A-01D-A34Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/16f479fd-302f-44ef-88ac-f966787cdc88

The open-access MAF lists 79 somatic variants for this specimen: 64 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 14, Frame Shift Del 11, Frame Shift Ins 2, Splice Site 2, Intron 1, Splice Region 1, In Frame Del 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKMY1 | c.1375G>T p.G459C | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99801210; called by muse, mutect2, varscan2
- ARFIP2 | c.417G>T p.K139N | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99601407; called by muse, mutect2, varscan2
- BHMT2 | c.228T>A p.F76L | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as COSV99669932; called by muse, mutect2, varscan2
- CCDC32 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.43); PolyPhen benign (0.055); catalogued as COSV100785889; called by muse, mutect2, varscan2
- CD151 | c.335A>G p.Y112C | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100431676; called by muse, mutect2, varscan2
- CELA2A | c.342C>A p.N114K | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.103); catalogued as COSV100657487; called by muse, mutect2, varscan2
- CENPI | c.1866G>T p.L622F | Missense Mutation (SNP) | VAF 87/130 reads (67%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV99515000; called by muse, mutect2, varscan2
- CLK4 | c.1186A>G p.I396V | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.155); catalogued as COSV100308801; called by muse, mutect2, varscan2
- COG3 | c.514C>G p.L172V | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100596364; called by muse, mutect2, varscan2
- DBF4 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0.178); catalogued as COSV99719131; called by muse, mutect2, varscan2
- DNAJA4 | c.472G>T p.G158W (on ENST00000343789; = p.G187W on NM_018602.3) | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100655109; called by muse, mutect2, varscan2
- DNTTIP2 | c.1604A>T p.H535L | Missense Mutation (SNP) | VAF 71/249 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.045); catalogued as COSV100785136; called by muse, mutect2, varscan2
- ESRP2 | c.1268A>G p.K423R (on ENST00000565858 / NM_001365264.1; = p.K413R on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0.206); catalogued as COSV99251067; called by muse, mutect2, varscan2
- FEM1C | c.1010C>G p.T337S | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV99174345; called by muse, mutect2, varscan2
- FXR2 | c.480C>A p.F160L | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.05); catalogued as COSV100007050; called by muse, mutect2
- GFPT2 | c.1167G>T p.L389F | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT tolerated (1); PolyPhen probably damaging (0.969); catalogued as COSV99517259; called by muse, mutect2, varscan2
- GRAMD2B | c.382A>G p.S128G | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV99586937; called by muse, mutect2, varscan2
- HEATR5B | c.3557C>G p.S1186C | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV51849368, COSV99248175; called by muse, mutect2, varscan2
- KCTD19 | c.560G>T p.S187I | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV100430646; called by muse, varscan2
- KIF13B | c.3433A>C p.M1145L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101580520; called by muse, mutect2, varscan2
- KIF20B | c.1450A>T p.T484S | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV99589442; called by muse, mutect2, varscan2
- LARGE1 | c.1781T>C p.V594A | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100504552; called by muse, mutect2, varscan2
- LURAP1 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as COSV100915041; called by muse, mutect2, varscan2
- MAN1C1 | c.1717C>G p.P573A | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.329); catalogued as COSV99847764; called by muse, mutect2, varscan2
- MARS2 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.158); catalogued as COSV99986479; called by muse, mutect2
- MCM3AP | c.4739T>G p.I1580S | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV99386448; called by muse, mutect2, varscan2
- MIER2 | c.252C>A p.D84E | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV99315966; called by muse, mutect2, varscan2
- MYLK3 | c.866C>T p.S289L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs374905189; called by muse, mutect2, varscan2
- NALCN | c.2365-2A>G p.X789_splice | Splice Site (SNP) | VAF 90/208 reads (43%) | catalogued as COSV99212877; called by muse, mutect2, varscan2
- NIN | c.256C>G p.Q86E | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV99811530; called by muse, mutect2, varscan2
- NOP14 | c.1638C>T p.L546= | Splice Region (SNP) | VAF 19/43 reads (44%) | catalogued as rs771068984, COSV100054306; called by muse, mutect2, varscan2
- PALD1 | c.2346T>G p.I782M | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV54970335; called by muse, mutect2, varscan2
- RABAC1 | c.507C>G p.F169L | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.583); catalogued as COSV99706006; called by muse, mutect2, varscan2
- RILPL1 | c.101T>C p.V34A | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as COSV100971270; called by muse, mutect2, varscan2
- SEMA4D | c.1197G>T p.L399F | Missense Mutation (SNP) | VAF 66/165 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100357918; called by muse, mutect2, varscan2
- SOX18 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100450498; called by muse, mutect2, varscan2
- TBCD | c.1658T>A p.I553N | Missense Mutation (SNP) | VAF 65/152 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100832568; called by muse, mutect2, varscan2
- TMC1 | c.1662T>A p.N554K | Missense Mutation (SNP) | VAF 64/201 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99918565; called by muse, mutect2, varscan2
- TPRX1 | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs199739873, COSV59115440; called by muse, mutect2, varscan2
- TTN | c.34633C>G p.P11545A (on ENST00000591111; = p.P10618A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/150 reads (35%) | PolyPhen benign (0.06); catalogued as COSV100593381; called by muse, mutect2, varscan2
- TUBAL3 | c.24C>A p.H8Q | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.982); catalogued as COSV100990453; called by muse, mutect2, varscan2
- UNG | c.263G>A p.R88H (on ENST00000242576 / NM_080911.3; = p.R79H on NM_003362.4) | Missense Mutation (SNP) | VAF 64/111 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.467); catalogued as COSV99655181; called by muse, mutect2, varscan2
- VPS37A | c.1061A>G p.E354G | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV100248851; called by muse, mutect2, varscan2
- ZFYVE28 | c.621C>G p.D207E | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1247738389, COSV99342392; called by muse, mutect2, varscan2
- ZNF420 | c.1416G>T p.E472D | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV100421133; called by muse, mutect2
- ZNF420 | c.1417A>C p.K473Q | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100421136; called by muse, mutect2
- ZNF442 | c.1759C>T p.L587F | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0.059); catalogued as COSV99664228; called by muse, mutect2, varscan2
- ARID2 | c.2851_2852del p.P951Sfs*16 | Frame Shift Del (DEL) | VAF 18/113 reads (16%) | called by mutect2, pindel, varscan2
- CLCN5 | c.1168_1170dup p.N390dup | In Frame Ins (INS) | VAF 36/52 reads (69%) | called by mutect2, pindel, varscan2
- CNOT1 | c.1859dup p.L620Ffs*60 | Frame Shift Ins (INS) | VAF 11/44 reads (25%) | called by mutect2, pindel, varscan2
- CRYBG2 | c.3464del p.M1155Rfs*31 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | called by mutect2, pindel*, varscan2
- GNL2 | c.1409_1416del p.P471Sfs*27 | Frame Shift Del (DEL) | VAF 16/42 reads (38%) | called by mutect2, pindel, varscan2
- IGHG4 | c.640A>C p.K214Q | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- MICB | c.799del p.W267Gfs*78 | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | called by mutect2, pindel, varscan2
- MUC17 | c.90del p.S30Rfs*2 | Frame Shift Del (DEL) | VAF 40/112 reads (36%) | called by mutect2, pindel*, varscan2
- PGLYRP4 | c.23del p.F8Sfs*65 | Frame Shift Del (DEL) | VAF 34/97 reads (35%) | called by mutect2, pindel, varscan2
- PLEKHA5 | c.431_432+1del p.X144_splice | Splice Site (DEL) | VAF 12/52 reads (23%) | called by mutect2, pindel, varscan2
- POLR2D | c.111dup p.H38Sfs*12 | Frame Shift Ins (INS) | VAF 40/116 reads (34%) | called by mutect2, pindel, varscan2
- RRBP1 | c.3369_3370del p.L1124Afs*5 (on ENST00000377813 / NM_001365613.2; = p.L691Afs*5 on NM_004587.3) | Frame Shift Del (DEL) | VAF 9/27 reads (33%) | called by pindel, varscan2
- STAT1 | c.81_82del p.M28Gfs*21 | Frame Shift Del (DEL) | VAF 59/189 reads (31%) | called by mutect2, pindel, varscan2
- TLN2 | c.5518del p.D1840Mfs*28 | Frame Shift Del (DEL) | VAF 14/39 reads (36%) | called by mutect2, pindel, varscan2
- TRIP4 | c.1299_1301del p.G434del | In Frame Del (DEL) | VAF 29/94 reads (31%) | called by pindel, varscan2
- VPS13A | c.6951del p.N2319Tfs*64 | Frame Shift Del (DEL) | VAF 63/197 reads (32%) | called by mutect2, pindel, varscan2
- WRAP53 | c.1275del p.Q426Sfs*3 | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | called by mutect2, pindel, varscan2
- DNAJC5 | c.306C>T p.S102= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs770247745, COSV100694129; called by muse, mutect2, varscan2
- EPHX3 | c.318C>T p.F106= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as COSV99691448; called by muse, mutect2, varscan2
- GLI3 | c.219G>A p.E73= | Silent (SNP) | VAF 77/186 reads (41%) | catalogued as rs1294404853, COSV101229723; called by muse, mutect2, varscan2
- HECTD4 | c.10614G>C p.L3538= | Silent (SNP) | VAF 20/39 reads (51%) | catalogued as COSV101106680; called by muse, mutect2, varscan2
- HIF1A | c.1617T>G p.L539= | Silent (SNP) | VAF 35/97 reads (36%) | catalogued as COSV100048451; called by muse, mutect2, varscan2
- MAP3K19 | c.1554C>T p.V518= | Silent (SNP) | VAF 87/224 reads (39%) | catalogued as COSV100208032; called by muse, mutect2, varscan2
- OBSCN | c.20334A>G p.V6778= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as rs1282059218, COSV100801038; called by muse, mutect2, varscan2
- PCDHGA1 | c.195C>G p.R65= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as COSV100965921; called by muse, mutect2, varscan2
- PPP1R8 | c.39G>C p.L13= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV99360829; called by muse, mutect2, varscan2
- PRPF40B | c.66C>G p.P22= (on ENST00000380281; = p.P16= on NM_012272.3) | Silent (SNP) | VAF 37/127 reads (29%) | catalogued as COSV99979332, COSV99979897; called by muse, mutect2, varscan2
- RAB33A | c.108C>T p.I36= | Silent (SNP) | VAF 43/51 reads (84%) | catalogued as COSV57062079; called by muse, varscan2
- RPL4 | c.1119C>A p.G373= | Silent (SNP) | VAF 38/98 reads (39%) | catalogued as COSV100331044; called by muse, mutect2, varscan2
- SLC12A5 | c.960T>C p.H320= (on ENST00000454036 / NM_001134771.2; = p.H297= on NM_020708.5) | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV99715319; called by muse, mutect2, varscan2
- USP20 | c.2403C>T p.F801= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as rs777174383, COSV100204007; called by muse, mutect2, varscan2
- TTN | c.10360+2314G>T | Intron (SNP) | VAF 45/131 reads (34%) | catalogued as COSV100593383; called by muse, mutect2, varscan2
